Gene-level copy-number profile of tumor specimen HCM-BROD-0644-C25-06B from HCMI case HCM-BROD-0644-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.7 years (25,096 days).
Specimen HCM-BROD-0644-C25-06B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 21db46dd-cc2d-4b7d-bc4a-6041d599b83b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0644-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/97d6a442-af7a-4b19-a5d5-88424b0c8705

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 12; copy number 2: 2,660; copy number 3: 1,151; copy number 4: 25,762; copy number 5: 6,665; copy number 6: 15,800; copy number 7: 1,770; copy number 8: 2,305; copy number 9: 925; copy number 10: 940; copy number 11: 188; copy number 12: 329; copy number 13: 25; copy number 14: 81; copy number 16: 89; copy number 19: 50; copy number 20: 28; copy number 23: 20; copy number 27: 77; copy number 53: 11; copy number 80: 1; copy number 97: 5; copy number 164: 3.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:123,721,246–123,721,639, 1 gene (within-gene range 0–4): RPL27P12.
- chr17:19,600,860–19,605,933, 6 genes: AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,771 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–2,967,955, 83 genes, copy number 9–11 (broad region; genes not listed).
- chr5:25,909,503–26,013,025, 2 genes, copy number 12: MSNP1, RNU4-43P.
- chr5:26,669,346–29,983,114, 32 genes, copy number 10–12: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr5:31,053,565–37,753,435, 121 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr5:38,556,765–38,671,216, 1 gene, copy number 12 (within-gene range 8–12): LIFR-AS1.
- chr5:38,682,070–45,895,970, 102 genes, copy number 11–12 (broad region; genes not listed).
- chr6:29,925,983–30,597,179, 49 genes, copy number 9: HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1, HLA-W, MICD, HCG9, DDX39BP2, MCCD1P2, ZNRD1ASP, HLA-J, AL671277.2, ETF1P1, AL669914.3, AL669914.2, POLR1H, AL669914.4, PPP1R11, RNF39, TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10, TRIM15, TRIM26, PAIP1P1, HCG17, TRIM26BP, HLA-L, AL662795.2, HCG18, TRIM39, TRIM39-RPP21, RPP21, HLA-N, AL662795.1, UBQLN1P1, MICC, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877.
- chr6:30,983,718–33,147,767, 188 genes, copy number 9 (broad region; genes not listed).
- chr7:84,939,335–92,110,673, 74 genes, copy number 9–13 (broad region; genes not listed).
- chr7:97,732,084–99,325,826, 38 genes, copy number 10: TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1.
- chr8:110,609,241–113,436,939, 16 genes, copy number 9 (within-gene range 6–9): AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 9: AC055788.2.
- chr8:114,282,067–127,742,951, 177 genes, copy number 10–164 (broad region; genes not listed).
- chr9:61,642,383–61,662,690, 2 genes, copy number 10: Y_RNA, AL935212.1.
- chr12:55,716,036–59,064,238, 167 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr14:19,999,913–24,430,954, 376 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr14:26,208,036–51,730,727, 366 genes, copy number 10–27 (within-gene range 6–27) (broad region; genes not listed).
- chr15:84,526,781–85,958,971, 50 genes, copy number 10 (within-gene range 8–10): UBE2Q2P1, LINC00933, AC048382.5, ZSCAN2, AC048382.1, AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1.
- chr15:87,859,751–94,600,821, 183 genes, copy number 10–12 (broad region; genes not listed).
- chr15:95,186,634–99,390,729, 76 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr15:99,971,437–100,342,005, 1 gene, copy number 10 (within-gene range 8–10): ADAMTS17.
- chr15:100,074,081–101,295,282, 33 genes, copy number 10: RNA5SP402, AC022710.1, SPATA41, CERS3-AS1, CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1.
- chr15:101,295,419–101,305,737, 2 genes, copy number 10 (within-gene range 7–10): AC023024.1, AC023024.2.
- chr16:66,366,622–75,193,247, 336 genes, copy number 9 (broad region; genes not listed).
- chr16:75,218,988–86,961,268, 268 genes, copy number 9–10 (broad region; genes not listed).
- chr17:41,500,981–41,865,423, 24 genes, copy number 9: KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11.
- chr17:46,372,855–46,487,141, 1 gene, copy number 20: NSFP1.
- chr22:23,446,598–23,486,980, 2 genes, copy number 9: AP000344.1, FAM230I.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
